Surgical pathology report (de-identified scan), TCGA case TCGA-KO-8410, project TCGA-KICH (Kidney Chromophobe), tissue source site MD Anderson Cancer Center, specimen TCGA-KO-8410-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY:

CHROMOPHOBE RENAL CELL CARCINOMA (5.2 CM MAXIMUM DIMENSION), FUHRMAN
NUCLEAR GRADE

3, CONFINED TO THE KIDNEY. (SEE COMMENT)

Margins of resection free of tumor.

One lymph node, no tumor present.

Adrenal gland tissue, no tumor present.

COMMENT

Most of the cells in this chromophobe renal cell carcinoma possess eosinophilic cytoplasm. Extensive foci of hemorrhage are also present. The tumor is confined to the kidney and does not invade into the perinephric adipose tissue, renal sinus adipose tissue or the renal vein.

GROSS DESCRIPTION

(A) LEFT KIDNEY - A radical nephrectomy specimen including perinephric fat and portion of adrenal measuring 19.5 x 13.0 x 6.5 cm in toto. The kidney measures 9.0 x 5.5 x 5.0 cm. Only a small portion of the adrenal gland is present, which measures 2.0 x 2.0 x 0.3 cm. A segment of ureter measuring 2.0 cm in length.

A centrally located well-circumscribed tumor (measuring 5.2 x 5.0 x 4.7 cm) is present in the mid-to-lower pole. The cut surface of the tumor is tan-brown, with 80% of the surface area showing hemorrhage. Tumor is grossly confined to the renal capsule and is 3.0 cm from Gerota's fascia and 6.0 cm from the ureteral and vascular margins. Tumor abuts the renal pelvis, but does not grossly extend into the renal sinus fat. No renal vein invasion is seen.

The adrenal gland tissue is unremarkable. The remainder of the kidney is otherwise grossly unremarkable.

Portion of tumor is submitted for possible electron microscopy.

INK CODE: Black-Gerota's fascia.

SECTION CODE: A1, ureteral/vascular margin; A2, A3, grossly uninvolved kidney; A4, adrenal gland tissue; A5-A9, tumor in relation to perinephric fat; A10, A11, tumor in relation to renal sinus; A12, additional section of tumor. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

[REDACTED]

Source: NCI Genomic Data Commons file a77199db-7206-4df3-a1b1-7c4c19e13226 (TCGA-KO-8410.7EF2010A-CE34-4C99-87A9-D42C23E6F0BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).